Surgical pathology report (de-identified scan), TCGA case TCGA-F4-6809, project TCGA-COAD (Colon Adenocarcinoma), tissue source site Asterand, specimen TCGA-F4-6809-01A (Primary Tumor).

[page 1 of 2]
Formatted Path Report

LARGE INTESTINE TISSUE CHECKLIST

Specimen type: Abdominal perineal resection
Specimen size: Not specified
Tumor site: Sigmoid colon
Tumor size: 7.5 x 0 x 0 cm
Tumor features: Ulcerated
Histologic type: Adenocarcinoma
Histologic grade: Moderately differentiated
Tumor extent: Pericolonic tissues
Lymph nodes: 3/12 positive for metastasis (Adjacent fatty tissue 3/12)
Margins: Uninvolved
Evidence of neo-adjuvant treatment: Not specified
Additional pathologic findings: Not specified
Comments: None

[page 2 of 2]
Date of Procurement

[illegible]

Source: NCI Genomic Data Commons file aa66e95c-5ca9-42dc-97e4-a17b0eaf62bb (TCGA-F4-6809.3EEF31F7-8C59-4B40-B441-DAAE9CB87C92.PDF), Data Release 46.0 - August 10, 2026; text from the OCR (chandra-v1.5.0).